Somatic mutation profile of tumor specimen MMRF_1992_1_PB_CD138pos (aliquot MMRF_1992_1_PB_CD138pos_T3_KBS5U_L07273) from MMRF case MMRF_1992, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.6 years (19,595 days).
Specimen MMRF_1992_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db4401a0-95b2-40f7-bac4-db0f055a2a7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1992_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1992_1_PB_CD3pos_C5_KBS5U_L07274; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b428399-1fd4-4672-81df-3614ede67c3b

The open-access MAF lists 32 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 12, Missense Mutation 8, 5'UTR 3, Intron 3, Silent 2, 5'Flank 1, RNA 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPS1 | c.3194C>A p.A1065E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770471782, CM114376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO36 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs747866198; called by muse, mutect2
- PRMT1 | c.643+6C>T | Splice Region (SNP) | VAF 16/135 reads (12%) | catalogued as rs372587638; called by muse, mutect2, varscan2
- ADAMTS2 | c.2169A>T p.K723N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP10A | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- GRWD1 | c.111_127del p.G38Rfs*27 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- MISP | c.1591G>C p.A531P | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SYNCRIP | c.1280T>A p.M427K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); called by muse, mutect2
- TRIM65 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TSHR | c.1902C>G p.F634L | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCNJL | c.915C>T p.A305= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs745814652, COSV57445825; called by muse, mutect2, varscan2
- HLA-F | c.96T>C p.A32= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- ABHD14A | chr3:51973844 G>A | 5'Flank (SNP) | VAF 18/30 reads (60%) | catalogued as rs1199787106; called by muse, mutect2, varscan2
- ADAM22 | c.993-308A>T | Intron (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- AKT3 | c.*609_*612del | 3'UTR (DEL) | VAF 3/21 reads (14%) | catalogued as rs139770173; called by mutect2, pindel*
- ANKRD45 | c.-39C>G | 5'UTR (SNP) | VAF 41/112 reads (37%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.-213A>G | 5'UTR (SNP) | VAF 37/236 reads (16%) | called by muse, mutect2, varscan2
- ATP2A1 | c.*210A>C | 3'UTR (SNP) | VAF 49/186 reads (26%) | called by muse, mutect2, varscan2
- CARMIL3 | c.*224T>C | 3'UTR (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- CDK12 | c.-2G>T | 5'UTR (SNP) | VAF 18/46 reads (39%) | catalogued as COSV101420441; called by muse, varscan2
- CST9 | c.*376C>T | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- DNM1P46 | n.970C>T | RNA (SNP) | VAF 22/39 reads (56%) | catalogued as rs375152504; called by muse, mutect2, varscan2
- DYNLL1 | c.133-127T>C | Intron (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- FAM172A | c.*1676A>G | 3'UTR (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2
- MYO15B | c.7984-38G>A | Intron (SNP) | VAF 21/40 reads (53%) | catalogued as rs922216903; called by muse, mutect2, varscan2
- PDK4 | c.*750T>C | 3'UTR (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- PIK3C2A | c.*1095T>G | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- PLAG1 | c.*1347C>A | 3'UTR (SNP) | VAF 16/76 reads (21%) | called by mutect2, varscan2
- SOX4 | c.*1156A>G | 3'UTR (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.*359A>G | 3'UTR (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- WDR37 | c.*2655G>C | 3'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- ZNF561 | c.*2041G>A | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
